Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6586, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6586-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT AND TRANSVERSE COLON

SPECIMEN(S):

A. RIGHT AND TRANSVERSE COLON

GROSS DESCRIPTION:

A. RIGHT AND TRANSVERSE COLON

Received fresh and labeled "right transverse colon", it consists of a right hemicolectomy with a portion of terminal ileum. The segment of terminal ileum measures 7.0 cm in length. The right colon measures 33.0 cm in length. The proximal (ileal) surgical margin measures 3.5 cm in circumference, and the distal (colonic) surgical margin measures 8.0 cm in circumference. An appendix is identified and measures 5.5 cm in length x 0.6 cm in width. Upon opening the specimen, a tumor mass is identified, located 7.0 cm from the distal surgical margin. This mass is tan colored, measures 4.0 x 4.0 x 1.1 cm and has heaped-up edges around its periphery, without obvious central ulceration. In addition to the primary mass, there are several minute (0.2 to 0.4 cm in diameter) polypoid lesions, 3-4 in the proximal ascending colon (proximal to the primary mass) and 1 in the distal aspect of the specimen (distal to the tumor mass). No other mucosal lesions are identified. Portions of the primary tumor mass and representative normal colon are procured. Summary of sections:

- A1: Proximal surgical margin
- A2: Distal surgical margin
- A3-A9: Primary tumor mass, blocked out and submitted entirely
- A10: Additional subserosal fat subjacent to primary mass
- A11: Representative terminal ileum
- A12: Representative cecum
- A13: Representative proximal colon with polypoid lesion
- A14: Representative distal colon with polypoid lesion
- A15: Appendix base and mid-portion
- A16: Appendix tip
- A17-A21: Each have one lymph node, bisected
- A22: Two lymph nodes, each bisected (one is inked black)
- A23: Six possible lymph nodes
- A24: Four possible lymph nodes
- A25: Six possible lymph nodes
- A26: One lymph node, bisected

DIAGNOSIS:

A. COLON, RIGHT AND TRANSVERSE, RESECTION:

- INVASIVE ADENOCARCINOMA, WITH MUCINOUS FEATURES, MODERATELY DIFFERENTIATED.
- 4.0 CM IN GREATEST DIMENSION.
- 4.0 X 1.1 CM IN ADDITIONAL DIMENSIONS.
- INVADING INTO THE SUBSEROA.
- THE PROXIMAL, DISTAL, AND RADIAL MARGINS ARE NEGATIVE FOR TUMOR.
- ANGIOLYMPHATIC INVASION IS PRESENT.
- NO PERINEURAL INVASION IDENTIFIED.
- ASSOCIATED WITH ADENOMATOUS CHANGE.
- TUBULAR ADENOMAS ARE PRESENT AWAY FROM THE TUMOR.
- APPENDIX WITH NO HISTOPATHOLOGICAL ABNORMALITIES.
- NO MALIGNANCY IDENTIFIED IN SEVENTEEN LYMPH NODES (0/17).

SYNOPTIC REPORT - COLON & RECTUM

Specimens Involved

Specimens: A: RIGHT AND TRANSVERSE COLON

Specimen Type: Right hemicolectomy

Tumor Site: Right (ascending) colon

Tumor Configuration: Infiltrative

Tumor size: 4cm Additional dimensions 4cm x 1.1cm

WHO Classification

Adenocarcinoma 8140/3

[page 2 of 2]
[REDACTED]

Histologic Grade: G2: Moderately differentiated
Extent of Invasion: Subserosa
Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)
Venous/Lymphatic Invasion: Present
Perineural Invasion: Absent
Additional Pathologic Findings: None identified
Extent of Resection: R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes: Negative 0 / 17
Implants: Absent
Pathological Staging (pTNM): pT 3 N 0 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Colon ca

[REDACTED]

Source: NCI Genomic Data Commons file d1005446-5dad-4bce-976a-fa2434fc6900 (TCGA-G4-6586.6B0870C1-2A5A-403F-9A30-770A10928CBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).